Somatic mutation profile of tumor specimen TCGA-XF-AAN1-01A (aliquot TCGA-XF-AAN1-01A-31D-A42E-08) from TCGA case TCGA-XF-AAN1, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 75.8 years (27,687 days).
Specimen TCGA-XF-AAN1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c6ba1d7f-c5f7-4102-a90f-63aba8abdcb3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XF-AAN1-10A (Blood Derived Normal), aliquot TCGA-XF-AAN1-10A-01D-A42H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4a1ee53d-5b8c-4a8c-b36f-e492fed3e47b

The open-access MAF lists 100 somatic variants for this specimen: 66 protein-altering or splice-affecting, 33 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 59, Silent 33, Splice Site 2, Nonsense Mutation 2, Frame Shift Ins 1, Translation Start Site 1, Splice Region 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1393C>T p.R465C (on ENST00000281708 / NM_001349798.2; = p.R385C on NM_018315.5) | Missense Mutation (SNP) | VAF 33/98 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867384286, COSV55891008, COSV55897912, COSV99654845; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FGFR3 | c.*167A>T | 3'UTR (SNP) | VAF 88/98 reads (90%) | catalogued as rs121913484, CM950471, COSV53390047; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCB7 | c.2189A>T p.E730V (on ENST00000373394 / NM_001271696.3; = p.E731V on NM_004299.6) | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.164); catalogued as COSV53721312; called by muse, mutect2, varscan2
- ALG10 | c.1359C>A p.F453L | Missense Mutation (SNP) | VAF 58/123 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV56793012; called by muse, mutect2, varscan2
- AMPD1 | c.1526G>T p.G509V | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.989); catalogued as COSV62417021; called by muse, mutect2, varscan2
- ANKRD26 | c.4534G>C p.E1512Q | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.412); catalogued as COSV65776522; called by muse, mutect2, varscan2
- ARHGEF12 | c.1726C>G p.P576A | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV63104996, COSV63105882, COSV63107238; called by muse, mutect2, varscan2
- ATAD5 | c.3010G>C p.E1004Q | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV58976209; called by muse, mutect2, varscan2
- ATP8B2 | c.2956G>C p.E986Q (on ENST00000672630; = p.E953Q on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/71 reads (8%) | SIFT tolerated (0.44); PolyPhen benign (0.036); catalogued as COSV59246994; called by muse, mutect2
- BCLAF1 | c.1853-2A>C p.X618_splice | Splice Site (SNP) | VAF 45/102 reads (44%) | catalogued as COSV50358748; called by muse, mutect2, varscan2
- CAPN1 | c.1114G>T p.E372* | Nonsense Mutation (SNP) | VAF 10/16 reads (63%) | catalogued as COSV99658981; called by muse, varscan2
- CASP10 | c.734C>G p.T245R | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as COSV53779293; called by muse, mutect2, varscan2
- CD300E | c.529G>A p.V177M | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.225); catalogued as rs113824696, COSV60790979; called by muse, mutect2, varscan2
- CELSR3 | c.1066G>A p.E356K | Missense Mutation (SNP) | VAF 35/70 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs770585899, COSV50841296, COSV50842619; called by muse, mutect2, varscan2
- CHRM5 | c.1244C>T p.T415M | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.214); catalogued as rs193093417, COSV67248269; called by muse, mutect2, varscan2
- CLTC | c.3247C>T p.Q1083* | Nonsense Mutation (SNP) | VAF 6/71 reads (8%) | catalogued as COSV52245221; called by muse, mutect2
- CNTN5 | c.854C>T p.T285M | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs777370237, COSV54297226, COSV54327473; called by muse, mutect2, varscan2
- CPS1 | c.4220C>T p.P1407L | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT tolerated (0.61); PolyPhen benign (0.007); catalogued as rs1390873960, COSV51807762; called by muse, mutect2, varscan2
- CSPG4 | c.3727C>T p.R1243W | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.232); catalogued as rs370243406, COSV57897804, COSV57899148; called by muse, mutect2, varscan2
- CTPS2 | c.1587T>A p.F529L | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.606); catalogued as COSV63723200; called by muse, mutect2, varscan2
- DOK1 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 14/25 reads (56%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.827); catalogued as rs577425194, COSV51209416; called by muse, mutect2, varscan2
- ERICH3 | c.959G>T p.G320V | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1184201586, COSV58611212; called by muse, mutect2, varscan2
- ESYT3 | c.787G>A p.G263R | Missense Mutation (SNP) | VAF 53/118 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV56680905; called by muse, mutect2, varscan2
- FAT4 | c.9323C>T p.S3108F | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.626); catalogued as rs1161211356, COSV58694446; called by muse, mutect2, varscan2
- FBN3 | c.1438G>A p.A480T | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT tolerated (0.57); PolyPhen benign (0.018); catalogued as COSV54465203; called by muse, mutect2, varscan2
- FSTL5 | c.478T>C p.Y160H | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.915); catalogued as COSV60206927; called by muse, mutect2, varscan2
- FTHL17 | c.253G>T p.D85Y | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV63266778, COSV63267286; called by muse, mutect2, varscan2
- GOLGB1 | c.8575G>C p.E2859Q | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.895); catalogued as rs1269638564, COSV100510346, COSV61467636; called by muse, mutect2, varscan2
- HLA-A | c.563G>A p.C188Y | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.588); catalogued as CM068505, COSV65138931; called by muse, mutect2, varscan2
- HOXB4 | c.493T>G p.S165A | Missense Mutation (SNP) | VAF 49/92 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.672); catalogued as COSV60178761; called by muse, mutect2, varscan2
- IKZF1 | c.706C>A p.L236M | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as rs1386107897, COSV100498880, COSV58781801; called by muse, mutect2, varscan2
- INF2 | c.1663C>T p.R555W | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as COSV53029441; called by muse, mutect2, varscan2
- INTS6 | c.2341G>C p.E781Q | Missense Mutation (SNP) | VAF 47/105 reads (45%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV60879161; called by muse, mutect2, varscan2
- ITGA8 | c.1151G>A p.G384E | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV65229184; called by muse, mutect2, varscan2
- KCNN3 | c.1733A>G p.Q578R (on ENST00000618040 / NM_001204087.1; = p.Q563R on NM_002249.6) | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.614); catalogued as COSV55220524; called by muse, mutect2, varscan2
- KIF1A | c.1298C>T p.A433V | Missense Mutation (SNP) | VAF 18/22 reads (82%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.831); catalogued as COSV57493951; called by muse, mutect2, varscan2
- MAGEB6 | c.77C>T p.T26M | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.776); catalogued as COSV66872557, COSV66873414; called by muse, mutect2, varscan2
- NALCN | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT tolerated (0.22); PolyPhen benign (0.061); catalogued as rs1029379718, COSV51926942; called by muse, mutect2, varscan2
- NOX4 | c.804G>T p.K268N | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV54446408, COSV54457576; called by muse, mutect2, varscan2
- NYNRIN | c.3904T>G p.S1302A | Missense Mutation (SNP) | VAF 50/121 reads (41%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.007); catalogued as COSV66843399; called by muse, mutect2, varscan2
- PAFAH1B3 | c.227G>A p.G76D | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT tolerated (0.61); PolyPhen benign (0.158); catalogued as COSV50608887; called by muse, mutect2
- PALMD | c.971C>T p.P324L | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs1303240817, COSV54165425; called by muse, mutect2, varscan2
- PCDHA12 | c.1858A>T p.I620F | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.021); catalogued as COSV56520525; called by muse, mutect2, varscan2
- PCNT | c.7088C>T p.A2363V | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.014); catalogued as rs1316353380, COSV64030126; called by muse, mutect2, varscan2
- PDS5A | c.3217G>A p.E1073K | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.998); catalogued as COSV57827877; called by muse, mutect2, varscan2
- PIGG | c.2070C>T p.S690= (on ENST00000453061 / NM_001127178.3; = p.S682= on NM_017733.4) | Splice Region (SNP) | VAF 5/18 reads (28%) | catalogued as rs559106384, COSV56319382; called by muse, mutect2
- PKHD1 | c.5707G>T p.V1903F | Missense Mutation (SNP) | VAF 32/56 reads (57%) | SIFT tolerated (0.08); PolyPhen benign (0.15); catalogued as COSV61884120, COSV61891662; called by muse, mutect2, varscan2
- PRR11 | c.484G>A p.V162I | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.037); catalogued as rs753441898, COSV51877666, COSV51879717; called by muse, mutect2, varscan2
- PSMB2 | c.526C>T p.P176S | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.775); catalogued as COSV64698929; called by muse, mutect2, varscan2
- RNF213 | c.9037A>T p.S3013C | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); catalogued as COSV60401972; called by muse, mutect2, varscan2
- SLC7A3 | c.1628C>A p.A543D | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.824); catalogued as COSV53228128; called by muse, mutect2, varscan2
- SPATA5L1 | c.1061T>A p.L354Q | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1269675386, COSV59745078; called by muse, mutect2, varscan2
- SPTAN1 | c.7415A>G p.N2472S | Missense Mutation (SNP) | VAF 21/25 reads (84%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV63988239; called by muse, mutect2, varscan2
- SRC | c.301A>G p.T101A | Missense Mutation (SNP) | VAF 53/183 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as COSV62440349; called by muse, mutect2, varscan2
- TET3 | c.3322G>A p.E1108K | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1340645582, COSV101328188; called by muse, mutect2, varscan2
- THSD7A | c.1466T>C p.M489T | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs1278457002, COSV70267666; called by muse, mutect2, varscan2
- TMED10 | c.539-3_539-2del p.X180_splice | Splice Site (DEL) | VAF 17/44 reads (39%) | catalogued as rs1566667993, COSV57848183; called by mutect2, pindel, varscan2
- TREH | c.134C>T p.A45V | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT deleterious (0); PolyPhen benign (0.41); catalogued as rs1555145383, COSV99874868; called by muse, mutect2, varscan2
- TRIO | c.2134C>T p.R712C | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs199843575; called by muse, mutect2, varscan2
- TRRAP | c.3601G>A p.G1201R | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV62838031; called by muse, mutect2, varscan2
- TTN | c.42727C>G p.L14243V (on ENST00000591111; = p.L6819V on NM_003319.4) | Missense Mutation (SNP) | VAF 6/15 reads (40%) | PolyPhen probably damaging (0.996); catalogued as COSV60169678, COSV60290931; called by muse, mutect2, varscan2
- ZIC4 | c.872C>T p.S291L | Missense Mutation (SNP) | VAF 32/57 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as rs916708888, COSV67172681, COSV67173104; called by muse, mutect2, varscan2
- ZNF746 | c.970G>T p.A324S | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT tolerated (0.78); PolyPhen benign (0.001); catalogued as rs748411008, COSV61408046; called by muse, mutect2, varscan2
- ZNF750 | c.33G>T p.K11N | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53961189; called by muse, mutect2, varscan2
- ZNF93 | c.912G>C p.K304N | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV59376641; called by muse, mutect2, varscan2
- ELF3 | c.775dup p.D259Gfs*42 | Frame Shift Ins (INS) | VAF 26/54 reads (48%) | called by mutect2, pindel, varscan2
- TRGV4 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 25/34 reads (74%) | SIFT tolerated (0.16); PolyPhen benign (0.291); called by muse, mutect2, varscan2
- ACAN | c.1527G>A p.S509= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as rs371049725; ClinVar: uncertain significance; called by muse, varscan2
- ADGRG7 | c.996C>T p.F332= | Silent (SNP) | VAF 24/46 reads (52%) | catalogued as COSV56298462; called by muse, mutect2, varscan2
- AMACR | c.321G>A p.L107= | Silent (SNP) | VAF 19/54 reads (35%) | catalogued as COSV59461794; called by muse, mutect2, varscan2
- ARHGAP32 | c.5532C>T p.G1844= (on ENST00000310343 / NM_001378025.1; = p.G1495= on NM_014715.4) | Silent (SNP) | VAF 15/33 reads (45%) | catalogued as COSV59850983; called by muse, mutect2, varscan2
- BVES | c.1059A>G p.T353= | Silent (SNP) | VAF 39/74 reads (53%) | catalogued as rs778352395, COSV58948720; called by muse, mutect2, varscan2
- CDC25A | c.270G>A p.G90= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as COSV56771496; called by muse, mutect2, varscan2
- CELF2 | c.1083G>A p.A361= (on ENST00000416382 / NM_001025077.3; = p.A374= on NM_006561.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 25/55 reads (45%) | catalogued as rs370482171, COSV59980682; called by muse, mutect2, varscan2
- CENPM | c.180G>A p.R60= | Silent (SNP) | VAF 11/21 reads (52%) | catalogued as COSV53245424; called by muse, mutect2, varscan2
- CHD8 | c.6354G>A p.E2118= (on ENST00000646647 / NM_001170629.2; = p.E1839= on NM_020920.4) | Silent (SNP) | VAF 16/32 reads (50%) | catalogued as COSV63037088; called by muse, mutect2, varscan2
- DMBT1 | c.7122C>T p.V2374= (on ENST00000338354 / NM_001377530.1; = p.V1617= on NM_004406.3) | Silent (SNP) | VAF 58/124 reads (47%) | catalogued as rs758484778, COSV57549968; called by muse, mutect2, varscan2
- GALC | c.1572C>T p.G524= | Silent (SNP) | VAF 35/81 reads (43%) | catalogued as rs753164684, COSV54327217; called by muse, mutect2, varscan2
- GPC6 | c.606C>T p.D202= | Silent (SNP) | VAF 31/63 reads (49%) | catalogued as rs376665919, COSV65519523; called by muse, mutect2, varscan2
- HIF3A | c.1011C>T p.V337= (on ENST00000377670 / NM_152795.4; = p.V268= on NM_022462.4) | Silent (SNP) | VAF 13/56 reads (23%) | catalogued as rs1212730011, COSV52200633; called by muse, mutect2, varscan2
- KCNT2 | c.2079A>G p.P693= | Silent (SNP) | VAF 73/152 reads (48%) | catalogued as COSV54090054; called by muse, mutect2, varscan2
- KLHDC4 | c.465C>G p.L155= | Silent (SNP) | VAF 58/134 reads (43%) | catalogued as COSV54509526; called by muse, mutect2, varscan2
- KLHL4 | c.69T>C p.S23= | Silent (SNP) | VAF 53/114 reads (46%) | catalogued as COSV64144401; called by muse, mutect2, varscan2
- NCK1 | c.45C>G p.A15= | Silent (SNP) | VAF 25/61 reads (41%) | catalogued as COSV56638239; called by muse, mutect2, varscan2
- NLE1 | c.1263G>A p.A421= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as rs145494138; called by muse, mutect2, varscan2
- OR2T8 | c.141T>C p.I47= | Silent (SNP) | VAF 21/64 reads (33%) | catalogued as COSV60663433; called by muse, mutect2, varscan2
- OTOP2 | c.772C>T p.L258= | Silent (SNP) | VAF 68/241 reads (28%) | catalogued as COSV58882546; called by muse, mutect2, varscan2
- PCDHB9 | c.672G>A p.G224= | Silent (SNP) | VAF 29/67 reads (43%) | called by muse, mutect2, varscan2
- PRDM16 | c.1536C>T p.P512= | Silent (SNP) | VAF 41/88 reads (47%) | catalogued as rs368073318, COSV54582082; ClinVar: likely benign; called by muse, mutect2, varscan2
- RADX | c.2550T>C p.S850= | Silent (SNP) | VAF 45/100 reads (45%) | catalogued as rs1168796767, COSV65319258; called by muse, mutect2, varscan2
- RPS6KA2 | c.1635G>A p.G545= | Silent (SNP) | VAF 17/42 reads (40%) | catalogued as rs1252098878, COSV55823898; called by muse, mutect2, varscan2
- RYR1 | c.14085C>T p.D4695= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as rs1248688892, COSV100615395; called by muse, mutect2
- SCRN3 | c.285A>G p.V95= | Silent (SNP) | VAF 50/111 reads (45%) | catalogued as rs1363858192, COSV55808690; called by muse, mutect2, varscan2
- SLC11A1 | c.1014C>T p.N338= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as rs377174618; called by muse, mutect2, varscan2
- SLC9A6 | c.1750T>C p.L584= | Silent (SNP) | VAF 17/34 reads (50%) | catalogued as COSV65788403; called by muse, mutect2, varscan2
- TNFSF9 | c.618G>C p.L206= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as COSV99832489; called by muse, mutect2
- TRIB2 | c.573C>T p.V191= | Silent (SNP) | VAF 33/72 reads (46%) | catalogued as rs1485255290, COSV50227252; called by muse, mutect2, varscan2
- UNC93A | c.939C>T p.V313= | Silent (SNP) | VAF 47/96 reads (49%) | catalogued as COSV57807584, COSV57809392; called by muse, mutect2, varscan2
- VPS35 | c.144T>C p.N48= | Silent (SNP) | VAF 20/49 reads (41%) | catalogued as rs769097906, COSV54479845; called by muse, mutect2, varscan2
- WDR70 | c.1635G>T p.R545= | Silent (SNP) | VAF 6/128 reads (5%) | catalogued as COSV54276901; called by muse, mutect2
